Somatic mutation profile of tumor specimen TCGA-B6-A0I9-01A (aliquot TCGA-B6-A0I9-01A-11W-A050-09) from TCGA case TCGA-B6-A0I9, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 62.4 years (22,798 days).
Specimen TCGA-B6-A0I9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50bd60e0-ad13-404b-8429-03abb024538a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0I9-10A (Blood Derived Normal), aliquot TCGA-B6-A0I9-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54221450-2adf-4363-996b-2b5c3343a4b9

The open-access MAF lists 75 somatic variants for this specimen: 57 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 17, Frame Shift Del 4, Nonsense Mutation 4, Frame Shift Ins 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 55/110 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.10240G>A p.A3414T | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.141); catalogued as rs367666935; called by muse, mutect2, varscan2
- ABCA4 | c.3560C>T p.T1187M | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.223); catalogued as COSV64673191; called by muse, mutect2, varscan2
- AC004593.2 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 76/563 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs373908314; called by muse, varscan2
- ADAMTS12 | c.1576T>A p.C526S | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61261979; called by muse, mutect2, varscan2
- ANTXR1 | c.1130C>T p.T377M | Missense Mutation (SNP) | VAF 107/242 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201850545, COSV58012988; called by muse, mutect2, varscan2
- ATP10A | c.3800C>A p.A1267D | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV63516757; called by muse, mutect2, varscan2
- ATP7B | c.4318C>T p.R1440W | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); catalogued as rs543334965, COSV54437898; called by muse, mutect2, varscan2
- AURKC | c.296+1G>C p.X99_splice (on ENST00000302804 / NM_001015878.2; = p.X65_splice on NM_003160.3) | Splice Site (SNP) | VAF 11/52 reads (21%) | catalogued as COSV57138098; called by muse, mutect2, varscan2
- CAMSAP1 | c.1732G>A p.G578R | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV56721868; called by muse, mutect2, varscan2
- CTDP1 | c.1751C>T p.T584M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.454); catalogued as rs777188795, COSV50002870; called by muse, mutect2, varscan2
- DISP1 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as rs760562145, CM166807, COSV52658246; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLGAP1 | c.1987G>T p.D663Y | Missense Mutation (SNP) | VAF 64/339 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV59800762; called by muse, mutect2, varscan2
- EVC2 | c.2206C>T p.L736F | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.902); catalogued as COSV60392792; called by muse, mutect2, varscan2
- GATA3 | c.1220_1221insT p.P408Afs*99 | Frame Shift Ins (INS) | VAF 18/91 reads (20%) | catalogued as COSV100650835, COSV100651341, COSV60515158, COSV60515274, COSV60515375, COSV60517941; called by mutect2, pindel
- GJA9 | c.1201A>G p.M401V | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781669136, COSV62532079; called by muse, mutect2, varscan2
- HACL1 | c.1601C>T p.T534I | Missense Mutation (SNP) | VAF 65/290 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100337202; called by muse, mutect2, varscan2
- HYDIN | c.1963G>T p.A655S | Missense Mutation (SNP) | VAF 69/483 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as COSV55483859; called by muse, mutect2, varscan2
- IGSF9B | c.1147C>T p.R383* | Nonsense Mutation (SNP) | VAF 14/21 reads (67%) | catalogued as rs1397187948, COSV58063992, COSV58067017; called by muse, mutect2, varscan2
- IL34 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs368143418; called by muse, mutect2, varscan2
- ITPR2 | c.3934T>A p.F1312I | Missense Mutation (SNP) | VAF 91/696 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67268691; called by muse, mutect2, varscan2
- KANK4 | c.2099A>G p.D700G | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV58092551; called by muse, mutect2, varscan2
- KCNK18 | c.774G>T p.L258F | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as COSV100571943, COSV57971649; called by muse, mutect2, varscan2
- KCNQ3 | c.928G>C p.G310R | Missense Mutation (SNP) | VAF 73/381 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66469730; called by muse, mutect2, varscan2
- LYN | c.1508C>A p.A503D | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV72923285; called by muse, mutect2, varscan2
- MLH3 | c.3726G>C p.E1242D (on ENST00000355774 / NM_001040108.2; = p.E1218D on NM_014381.3) | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.166); catalogued as COSV53154639; called by muse, mutect2, varscan2
- MPDZ | c.1364_1365del p.V455Afs*31 | Frame Shift Del (DEL) | VAF 77/270 reads (29%) | catalogued as rs1564026963; called by pindel, varscan2
- MYPN | c.2751G>C p.E917D | Missense Mutation (SNP) | VAF 139/602 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62733508; called by muse, mutect2, varscan2
- NPY | c.271C>T p.L91F | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV54215040; called by muse, mutect2, varscan2
- NSDHL | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | catalogued as CM107172, COSV64743775; called by muse, mutect2, varscan2
- OR1M1 | c.567C>A p.C189* | Nonsense Mutation (SNP) | VAF 22/90 reads (24%) | catalogued as COSV70036834; called by muse, mutect2, varscan2
- OR2D3 | c.850A>G p.K284E | Missense Mutation (SNP) | VAF 77/207 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV53492837; called by muse, mutect2, varscan2
- OR5D14 | c.71A>T p.K24M | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV59456122; called by muse, mutect2, varscan2
- OTOP2 | c.1606A>T p.I536F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58881717; called by muse, mutect2, varscan2
- PELP1 | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.621); catalogued as rs1270099671, COSV52587611; called by muse, mutect2, varscan2
- PRAMEF2 | c.902C>T p.T301I | Missense Mutation (SNP) | VAF 19/261 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV99535176; called by muse, mutect2
- PRDM1 | c.461A>G p.E154G | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as COSV64845185; called by muse, mutect2, varscan2
- PRICKLE3 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs200820390, COSV66234494; called by muse, mutect2, varscan2
- PRKN | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 122/284 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as CM080478, COSV58222528; called by muse, mutect2, varscan2
- RMDN1 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 41/91 reads (45%) | catalogued as COSV52205955; called by muse, mutect2, varscan2
- RNF10 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs767518780, COSV58044692; called by muse, mutect2, varscan2
- SERPINB3 | c.1099C>G p.H367D | Missense Mutation (SNP) | VAF 73/373 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52191331, COSV99380160; called by muse, mutect2, varscan2
- SLITRK2 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs373498501, COSV59428955; called by muse, mutect2
- SP3 | c.518T>G p.I173R | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59467440; called by muse, mutect2, varscan2
- SRCAP | c.9472C>G p.Q3158E | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as COSV52671816; called by muse, mutect2, varscan2
- STAG2 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV54357268; called by muse, mutect2, varscan2
- TMEM273 | c.290A>C p.K97T | Missense Mutation (SNP) | VAF 78/452 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as COSV65152766; called by muse, mutect2, varscan2
- TMTC4 | c.972G>T p.L324F (on ENST00000376234 / NM_001350577.2; = p.L343F on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV60892025; called by muse, mutect2, varscan2
- TRO | c.2542G>A p.G848S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV51500861; called by muse, mutect2, varscan2
- TTN | c.4783A>T p.I1595F (on ENST00000591111; = p.I1549F on NM_003319.4) | Missense Mutation (SNP) | VAF 69/282 reads (24%) | PolyPhen probably damaging (0.996); catalogued as COSV60021400; called by muse, mutect2, varscan2
- UNC93A | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775793583, COSV57808312; called by muse, mutect2, varscan2
- UTRN | c.4937C>G p.T1646S | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.92); catalogued as COSV62328962, COSV62334209; called by muse, mutect2, varscan2
- ZFP64 | c.1291G>T p.D431Y | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV53798534, COSV53802918; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2036A>T p.E679V | Missense Mutation (SNP) | VAF 5/136 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); called by muse, mutect2
- DNASE2 | c.415del p.A139Pfs*36 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- FAM171A1 | c.290del p.P97Qfs*17 | Frame Shift Del (DEL) | VAF 30/159 reads (19%) | called by mutect2, pindel, varscan2
- IVNS1ABP | c.1253_1254del p.Y418Cfs*11 | Frame Shift Del (DEL) | VAF 58/264 reads (22%) | called by mutect2, pindel, varscan2
- CHD4 | c.3678A>G p.K1226= (on ENST00000357008 / NM_001363606.2; = p.K1239= on NM_001273.5) | Silent (SNP) | VAF 58/227 reads (26%) | catalogued as COSV58900075; called by muse, mutect2, varscan2
- DNAJC13 | c.6354G>A p.Q2118= | Silent (SNP) | VAF 36/188 reads (19%) | catalogued as COSV53449791; called by muse, mutect2, varscan2
- ETV6 | c.813C>T p.S271= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV67149668; called by muse, mutect2, varscan2
- FBXO7 | c.675G>A p.P225= | Silent (SNP) | VAF 58/291 reads (20%) | catalogued as rs749321931, COSV56677687; called by muse, mutect2, varscan2
- FERD3L | c.201C>T p.C67= | Silent (SNP) | VAF 25/382 reads (7%) | catalogued as COSV51763558; called by muse, mutect2
- HOXD3 | c.258C>G p.L86= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV99980075; called by muse, mutect2
- KRTAP19-1 | c.252C>T p.Y84= | Silent (SNP) | VAF 68/302 reads (23%) | catalogued as rs1196043751, COSV66861156; called by muse, mutect2
- KRTAP20-2 | c.63C>T p.G21= | Silent (SNP) | VAF 24/484 reads (5%) | catalogued as rs1479456938, COSV100424482; called by muse, mutect2
- MECP2 | c.438C>T p.G146= | Silent (SNP) | VAF 48/133 reads (36%) | catalogued as rs61748386, COSV57653301; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRE11 | c.1287A>G p.V429= | Silent (SNP) | VAF 453/825 reads (55%) | catalogued as COSV60576418; called by muse, mutect2, varscan2
- NACA2 | c.540C>T p.D180= | Silent (SNP) | VAF 86/492 reads (17%) | catalogued as rs149192515; called by muse, mutect2
- RBM26 | c.2697G>A p.T899= (on ENST00000438737 / NM_001366735.2; = p.T872= on NM_022118.5) | Silent (SNP) | VAF 36/143 reads (25%) | catalogued as rs777098333, COSV57393986; called by muse, mutect2, varscan2
- RSAD2 | c.249C>T p.C83= | Silent (SNP) | VAF 18/293 reads (6%) | catalogued as COSV101149839; called by muse, mutect2
- STAT4 | c.2058A>T p.T686= | Silent (SNP) | VAF 75/281 reads (27%) | catalogued as COSV61829498; called by muse, mutect2, varscan2
- TTN | c.82410C>T p.D27470= (on ENST00000591111; = p.D20046= on NM_003319.4) | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs773566203, COSV60021351, COSV60397722; called by muse, mutect2, varscan2
- UGT8 | c.31C>T p.L11= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV60417768; called by muse, mutect2, varscan2
- VCPIP1 | c.3063C>T p.N1021= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as rs768637681, COSV60047057; called by muse, mutect2, varscan2
- CST7 | c.-43C>T | 5'UTR (SNP) | VAF 7/19 reads (37%) | catalogued as rs374159769; called by muse, mutect2, varscan2
